Somatic mutation profile of tumor specimen MMRF_2818_1_BM_CD138pos (aliquot MMRF_2818_1_BM_CD138pos_T1_KHS5U_L15704) from MMRF case MMRF_2818, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 50.8 years (18,538 days).
Specimen MMRF_2818_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8110c4bb-abeb-4b34-b855-9f49f3617f21.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2818_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2818_1_PB_WBC_C3_KHS5U_L15750; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f9379209-40b1-497d-a246-b6b2b20b689f

The open-access MAF lists 77 somatic variants for this specimen: 38 protein-altering or splice-affecting, 7 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 17, Intron 10, Silent 7, Nonsense Mutation 2, 3'Flank 2, 5'UTR 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 45/147 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABL1 | c.1804G>A p.A602T | Missense Mutation (SNP) | VAF 93/210 reads (44%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.014); catalogued as rs755568851, COSV59330881; called by muse, varscan2
- ADCY8 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV53895915, COSV53906214; called by muse, mutect2, varscan2
- AGBL3 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs926581325; called by muse, mutect2, varscan2
- CARNS1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs745605718, COSV57048100; called by muse, mutect2, varscan2
- H3C11 | c.197T>G p.L66R | Missense Mutation (SNP) | VAF 41/341 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV58899794; called by muse, mutect2, varscan2
- IGFALS | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs1249022434; called by muse, mutect2, varscan2
- IGHV2-70 | c.259A>T p.R87W | Missense Mutation (SNP) | VAF 88/151 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs568002484; called by muse, varscan2
- IGHV2-70 | c.100A>T p.T34S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs570621406; called by muse, varscan2
- IGHV3-30 | c.66G>C p.Q22H | Missense Mutation (SNP) | VAF 52/57 reads (91%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.03); catalogued as rs553647220; called by muse, varscan2
- IGLV3-1 | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 100/206 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs561290535; called by muse, varscan2
- MUC5B | c.17059G>A p.G5687R | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs561368471; called by muse, mutect2, varscan2
- PEAR1 | c.938A>G p.Q313R | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.692); catalogued as rs767363444, COSV52773451; called by muse, mutect2, varscan2
- PTAFR | c.971C>T p.T324M | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.925); catalogued as rs928602946; called by muse, mutect2, varscan2
- RUSC2 | c.1546C>T p.R516C | Missense Mutation (SNP) | VAF 27/197 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769971449, COSV63428536; called by muse, mutect2, varscan2
- TNC | c.6401C>T p.T2134I | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369462979; called by muse, mutect2, varscan2
- TPTE | c.773C>T p.S258F (on ENST00000618007 / NM_199261.4; = p.S240F on NM_199259.4) | Missense Mutation (SNP) | VAF 27/492 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as rs752229389; called by muse, mutect2
- VDR | c.1141G>T p.A381S | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.843); catalogued as COSV57468655; called by muse, mutect2, varscan2
- ABCA1 | c.3784T>C p.S1262P | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ABCC10 | c.-11-7C>A | Splice Region (SNP) | VAF 93/218 reads (43%) | called by muse, mutect2, varscan2
- ARHGAP15 | c.71_91del p.V24_N30del | In Frame Del (DEL) | VAF 30/329 reads (9%) | called by mutect2, pindel
- BAMBI | c.675C>G p.C225W | Missense Mutation (SNP) | VAF 26/201 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CAMK1G | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- CFAP65 | c.1568C>T p.A523V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CUL3 | c.1181A>G p.D394G | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FNDC7 | c.1391A>G p.K464R | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPR157 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- INPP4A | c.1412T>A p.I471N | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- KDM5A | c.1305A>C p.E435D | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- LRIG2 | c.182T>A p.L61* | Nonsense Mutation (SNP) | VAF 23/158 reads (15%) | called by muse, mutect2, varscan2
- MED16 | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 6/147 reads (4%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.96); called by muse, mutect2
- NRDE2 | c.1262A>T p.Y421F | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR12D3 | c.94A>G p.I32V | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD2L2 | c.1363A>G p.N455D | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.85); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- RGS18 | c.555del p.E185Dfs*9 | Frame Shift Del (DEL) | VAF 51/324 reads (16%) | called by mutect2, pindel, varscan2
- ROPN1L | c.616A>T p.I206L | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- SPTBN5 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- TSGA13 | c.371T>A p.L124* | Nonsense Mutation (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- BTNL9 | c.1293C>T p.F431= | Silent (SNP) | VAF 24/185 reads (13%) | catalogued as rs754599052; called by muse, mutect2, varscan2
- CCNT1 | c.1776C>G p.A592= | Silent (SNP) | VAF 64/138 reads (46%) | catalogued as rs976829739; called by muse, mutect2, varscan2
- DLG5 | c.4227G>A p.Q1409= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- KRT36 | c.1284C>A p.V428= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV60204821; called by muse, mutect2, varscan2
- MGAM2 | c.2967A>G p.A989= | Silent (SNP) | VAF 6/102 reads (6%) | catalogued as rs1409698041; called by muse, mutect2
- PCDH11X | c.2607A>G p.K869= | Silent (SNP) | VAF 61/190 reads (32%) | called by muse, mutect2, varscan2
- SNX4 | c.93C>T p.V31= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as rs1367692357; called by muse, mutect2, varscan2
- ABCD2 | c.*3704C>T | 3'UTR (SNP) | VAF 39/86 reads (45%) | catalogued as rs536675464; called by muse, mutect2, varscan2
- AC015802.6 | c.*3581G>C | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- ATIC | c.291-9G>A | Intron (SNP) | VAF 54/100 reads (54%) | called by muse, mutect2, varscan2
- BDKRB2 | c.75-113C>T | Intron (SNP) | VAF 25/136 reads (18%) | catalogued as rs1345699371; called by muse, mutect2, varscan2
- BHLHE40 | c.*954A>T | 3'UTR (SNP) | VAF 12/91 reads (13%) | called by muse, varscan2
- CAV1 | c.*932C>A | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- CD2AP | c.1108+91T>A | Intron (SNP) | VAF 3/21 reads (14%) | called by muse, mutect2
- CYHR1 | c.-120A>G | 5'UTR (SNP) | VAF 35/271 reads (13%) | catalogued as rs1324923010; called by muse, mutect2, varscan2
- ELMOD1 | c.*1508T>A | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- FZD10 | c.*78T>C | 3'UTR (SNP) | VAF 26/62 reads (42%) | called by muse, varscan2
- GDA | c.*2803T>G | 3'UTR (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- GMPPB | chr3:49719809 C>T | 3'Flank (SNP) | VAF 19/177 reads (11%) | called by muse, mutect2, varscan2
- GSTCD | chr4:105847236 G>A | 3'Flank (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2, varscan2
- HINFP | c.1139+65A>G | Intron (SNP) | VAF 36/86 reads (42%) | called by muse, mutect2
- HMGB1 | c.-15+68T>C | Intron (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- IGDCC4 | c.*2229T>C | 3'UTR (SNP) | VAF 16/90 reads (18%) | called by muse, mutect2, varscan2
- KCNK15 | c.*82A>T | 3'UTR (SNP) | VAF 22/139 reads (16%) | called by muse, mutect2, varscan2
- KIF25 | c.317+1476C>T | Intron (SNP) | VAF 6/30 reads (20%) | called by muse, mutect2
- MACROD2 | c.418+165090C>G | Intron (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2
- MAST1 | c.1639-24C>T | Intron (SNP) | VAF 34/180 reads (19%) | catalogued as rs542834653; called by muse, mutect2, varscan2
- MXRA5Y | n.7572C>T | RNA (SNP) | VAF 40/41 reads (98%) | catalogued as rs780865790; called by muse, mutect2, varscan2
- PNLIPRP3 | c.*591T>A | 3'UTR (SNP) | VAF 16/80 reads (20%) | called by muse, mutect2, varscan2
- PPP2R3A | c.*1249T>G | 3'UTR (SNP) | VAF 14/79 reads (18%) | called by muse, mutect2, varscan2
- RAPGEFL1 | c.*1844G>A | 3'UTR (SNP) | VAF 10/69 reads (14%) | catalogued as rs752910541; called by muse, mutect2, varscan2
- SERP1 | c.-3A>C | 5'UTR (SNP) | VAF 36/264 reads (14%) | called by mutect2, varscan2
- SLC6A13 | c.*196G>A | 3'UTR (SNP) | VAF 12/110 reads (11%) | called by muse, mutect2, varscan2
- TMEM131L | c.952-22T>C | Intron (SNP) | VAF 52/117 reads (44%) | called by muse, mutect2, varscan2
- TMX1 | c.*1164C>A | 3'UTR (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- UBE2NL | c.*671T>A | 3'UTR (SNP) | VAF 4/79 reads (5%) | called by muse, mutect2
- VPS8 | c.*523A>G | 3'UTR (SNP) | VAF 6/55 reads (11%) | called by muse, mutect2, varscan2
- ZFHX4 | c.*1512T>A | 3'UTR (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- ZMYM6 | c.428+2054A>C | Intron (SNP) | VAF 11/68 reads (16%) | called by muse, mutect2, varscan2
